Somatic mutation profile of tumor specimen MP2PRT-PATHHX-TMP1-A (aliquot MP2PRT-PATHHX-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATHHX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,985 days).
Specimen MP2PRT-PATHHX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbb0fcf6-1dbc-4d68-ad4c-90ff4445624d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHHX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHHX-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c45009ed-156f-4120-a4b8-eb586eb0d0d8

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 51/286 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913491, COSV54054678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 176/624 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs375753155; called by muse, mutect2, varscan2
- ANO9 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs772062472; called by muse, mutect2, varscan2
- C8orf33 | c.9C>T p.A3= | Splice Region (SNP) | VAF 255/565 reads (45%) | catalogued as rs746955353; called by muse, mutect2, varscan2
- CELSR1 | c.7817C>T p.S2606L | Missense Mutation (SNP) | VAF 105/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201155196, COSV99417093; called by muse, mutect2, varscan2
- CREBBP | c.4461C>A p.H1487Q | Missense Mutation (SNP) | VAF 251/516 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99269870; called by muse, varscan2
- EXOC3L2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 156/570 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as rs763296553; called by muse, mutect2
- GJA1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 214/602 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.432); catalogued as rs774210184, CM161897, COSV56996979; called by muse, mutect2, varscan2
- GSTA1 | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 48/422 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.606); catalogued as rs183821084, COSV100575456; called by muse, mutect2, varscan2
- TENM3 | c.7952C>T p.T2651M | Missense Mutation (SNP) | VAF 240/797 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs534196359; called by muse, mutect2, varscan2
- TMC1 | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 152/360 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs371947894; called by muse, mutect2, varscan2
- TNFRSF21 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 161/542 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772959706, COSV57281155; called by muse, mutect2, varscan2
- UNC93A | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 75/263 reads (29%) | catalogued as rs1417086028; called by muse, mutect2, varscan2
- NFIC | c.897C>A p.Y299* | Nonsense Mutation (SNP) | VAF 238/533 reads (45%) | called by muse, mutect2, varscan2
- PAN2 | c.2658_2661del p.H887Sfs*24 (on ENST00000425394 / NM_001127460.3; = p.H883Sfs*24 on NM_014871.5) | Frame Shift Del (DEL) | VAF 72/216 reads (33%) | called by mutect2, pindel, varscan2
- RSPH14 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 184/407 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 140/466 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ADNP2 | c.2157C>T p.S719= | Silent (SNP) | VAF 161/341 reads (47%) | catalogued as rs764522978; called by muse, mutect2, varscan2
- KIAA1549 | c.5079C>T p.D1693= | Silent (SNP) | VAF 290/643 reads (45%) | catalogued as rs552002443, COSV54315484; called by muse, mutect2, varscan2
- NEUROG3 | c.369G>A p.E123= | Silent (SNP) | VAF 230/538 reads (43%) | called by muse, mutect2, varscan2
- UGT1A6 | c.210C>T p.S70= | Silent (SNP) | VAF 181/391 reads (46%) | called by muse, mutect2, varscan2
- TRDJ1 | chr14:22449112 ins GAGGGGGGAGA | 5'Flank (INS) | VAF 70/234 reads (30%) | called by mutect2, varscan2
